Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A6IH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A6IH-01A (Primary Tumor).

[page 1 of 6]
Document Type: Anat Path Reports
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

* Final Report *

(Verified)

ICD-0-3
Carcinoma, squamous
cell NOS 8070/3
Site C6CF
Alveolar ridge
C03.9
path
mandible C41.1
JW 6/12/13

Patient Name: [REDACTED] Acc #: [REDACTED]
MRN: [REDACTED] DOB: [REDACTED] Head and Neck
Location: [REDACTED] Gender: F Collected:
Client: Received:
Submitting Phys: Reported:
Copy To Phys:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. LYMPH NODE, SUBMENTAL CONTENTS, NECK DISSECTION:

- ONE LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).
- FOCI OF CHRONIC GRANULOMATOUS INFLAMMATION.
- NEGATIVE FOR GMS-FUNGUS, PAS, ACID-FAST BACILLI AND CYTOKERATIN AE1/3.

B. LYMPH NODES, LEFT LEVEL IIB, NECK DISSECTION:

- TEN LYMPH NODES NEGATIVE FOR CARCINOMA (0/10).

C. LYMPH NODES, LEFT LEVEL III, LEFT, NECK DISSECTION:

- FOURTEEN LYMPH NODES NEGATIVE FOR CARCINOMA (0/14).
- NEGATIVE FOR GMS-FUNGUS AND CYTOKERATIN AE1/3.

D. FLOOR OF MOUTH MARGIN, LEFT, EXCISION, D1FS:

- BENIGN SQUAMOUS MUCOSA AND MINOR SALIVARY GLANDS, CHRONICALLY INFLAMED.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

E. POSTERIOR PHARYNGEAL MARGIN, EXCISION, E1FS:

- BENIGN SQUAMOUS MUCOSA AND LYMPHOID AGGREGATES.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

F. BUCCAL MARGIN, EXCISION, F1FS:

- BENIGN SQUAMOUS MUCOSA AND CHRONIC INFLAMMATION.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- SEE COMMENT.

G. LOWER LIP MARGIN, EXCISION, G1FS:

- BENIGN SQUAMOUS MUCOSA AND MINOR SALIVARY GLANDS, CHRONICALLY INFLAMED.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

H. PTERYGOID MUSCLE MARGIN, EXCISION, H1FS:

- SKELETAL MUSCLE BUNDLES AND SEGMENT OF PERIPHERAL NERVE.

[page 2 of 6]
- NEGATIVE FOR INVASIVE CARCINOMA.

I. GINGIVAL MARGIN, MEDIAL, EXCISION, I1FS:

- BENIGN SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

J. LYMPH NODES, LEFT LEVEL II, NECK DISSECTION:

- METASTATIC SQUAMOUS CELL CARCINOMA IN TWO OF FIVE LYMPH NODES (2/5).
- CHRONIC GRANULOMATOUS INFLAMMATION WITHIN LYMPH NODES.

K. BUCCAL FAT, LEFT, EXCISION:

- BENIGN FIBROADIPOSE TISSUE.
- NEGATIVE FOR INVASIVE CARCINOMA.

L. MANDIBLE AND LEVEL I NECK CONTENTS, LEFT, HEMIMANDIBULECTOMY AND LEVEL I NECK DISSECTION:

- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (4.6 X 4.4 X 4.0 CM).
- CARCINOMA IS SEEN INVADING MANDIBULAR BONE AND SKELETAL MUSCLE BUNDLES.
- PERINEURAL AND LYMPHOVASCULAR INVASION ARE PRESENT.
- ALL MUCOSAL, SOFT TISSUE AND BONY MARGINS (INCLUDES PARTS D-I) ARE NEGATIVE FOR

INVASIVE CARCINOMA.

- LEFT LEVEL I CONTENTS:

- METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF TWO LYMPH NODES (1/2).
- LARGEST DEPOSIT OF CARCINOMA MEASURES 1.6CM IN A 1.3CM LYMPH NODE.
- EXTRANODAL EXTENSION IS IDENTIFIED.
- SALIVARY GLAND PARENCHYMA EXHIBITING CHRONIC SIALADENITIS.
- SEE SYNOPSIS REPORT.

M. STERNOCLEIDOMASTOID MUSCLE, LEFT, EXCISION:

- SKELETAL MUSCLE BUNDLES AND FIBROVASCULAR CONNECTIVE TISSUE.
- NEGATIVE FOR INVASIVE CARCINOMA.

Comment

Part F: Chronic granulomatous inflammation is noted in several lymph nodes (Part A, J) as well as in association with the squamous cell carcinoma in the main specimen (Part N). In retrospective review of the frozen section of Part F, intraoperatively diagnosed as 'atypical focus cells surrounded by chronic inflammation – focus disappears on deeper frozen sections', most likely represents a focus of granulomatous inflammation.

Electronically Signed by

Assisted by:

Synoptic Worksheet

L. Hemimandibulectomy w/ neck contents level 1- fresh:

Clinical History:	No neoadjuvant therapy
Specimen:	Mandible
Received:	Fresh
Procedure:	Mandibulectomy: left hemimandibulectomy
	Neck (lymph node) dissection: Level I, II, III - left
Specimen Integrity:	Intact
Specimen Size:	Greatest dimension: 12 cm
	Additional dimension: 7.2 cm
	Additional dimension: 6.0 cm
Specimen Laterality:	Left
Tumor Site:	Mandible
Tumor Focality:	Single focus

[page 3 of 6]
Tumor Size:	Greatest dimension: 4.6 cm Additional dimension: 4.4 cm Additional dimension: 4.0 cm Measured from ulcerated surface
Tumor Description:	Exophytic Endophytic Ulcerated
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G2: Moderately differentiated
Margins:	Margins uninvolved by invasive carcinoma Distance from closest margin: 1.0 Unit of measurement: mm Margin(s): Less than 1.0mm from medial and lateral soft tissue margins. Margins uninvolved by carcinoma in situ (includes moderate and severe dysplasia)
Treatment Effect:	Not identified
Lymph-Vascular Invasion:	Present
Perineural Invasion:	Present
Lymph Nodes, Extranodal Extension:	Present
Pathologic Staging (pTNM):	
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT4b: Very advanced local disease. Tumor invades masticator space, pterygoid plates, or skull base, and/or encases internal carotid artery
Regional Lymph Nodes (pN):	pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension Number of regional lymph nodes examined: 32 Number of regional lymph nodes involved: 3 Size (greatest dimension) of the largest positive lymph node: 1.6 cm
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified

Clinical History

Malignant neoplasm of mandible. Free-flap.

Specimen(s) Received

A: Submentum neck contents
B: Level 2B
C: Level 3
D: Left floor of mouth margin, stitch - anterior
E: Posterior pharyngeal margin, stitch - superior
F: Buccal margin, stitch - anterior
G: Lower lip margin, stitch - medial
H: Pterygoid muscle margin
I: Medial gingival margin
J: Left level 2- fresh
K: Left buccal fat- fresh
L: Hemimandibulectomy w/ neck contents level 1- fresh
M: Left sternocleidomastoid muscle

Gross Description

Specimen A is received in formalin along with patient's name, medical record number and labeled as submentum neck contents. The specimen consists of an oriented fibroadipose tissue fragment which measures 2.8 x 1.6 x 1.2

[page 4 of 6]
cm. A total of 7 potential lymph nodes are identified in the tissue. The largest one measures 0.8 cm in diameter. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

A1: One lymph node, bisected
A2: Three potential lymph nodes
A3: Three potential lymph nodes

Specimen B is received in formalin along with patient's name, medical record number and labeled as left level 2B. The specimen consists of an oriented soft tissue fragment which measures 2.5 x 1.8 x 1.0 cm. A total of 9 potential lymph nodes are identified in the specimen. The largest one measures 0.8 cm in diameter. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

B1: Three potential lymph nodes
B2: Three potential lymph nodes
B3: One lymph node, bisected
B4: One lymph node, bisected
B5: One lymph node, bisected

Specimen C is received in formalin along with patient's name, medical record number and labeled as left level 3. The specimen consists of an oriented fibroadipose tissue which measures 4.0 x 3.5 x 2.0 cm. A total of 14 potential lymph nodes are identified. The largest one measures 1.5 cm in diameter. The specimen is submitted as follows. (Dictated by

CASSETTE SUMMARY:

C1, C2: Largest lymph node, bisected
C3: One potential lymph node, bisected
C4: One potential lymph node, bisected
C5: One potential lymph node, bisected
C6: One potential lymph node, bisected
C7: One potential lymph node, bisected
C8: One potential lymph node, bisected
C9: Two potential lymph nodes
C10: Three potential lymph nodes
C11: Two potential lymph nodes

Specimen D is received fresh along with patient's name, medical record number and labeled as left floor of mouth margin, frozen section, stitch anterior. The specimen consists of a strip of mucosa tissue which measures 4.0 x 0.4 x 0.4 cm. The specimen is submitted for intraoperative consultation and entirely submitted in cassette D1FS. (Dictated by

Specimen E is received fresh along with patient's name, medical record number and labeled as posterior pharyngeal margin, stitch superior, frozen section. The specimen consists of a fragment of mucosa which measures 1.2 x 0.4 x 0.3 cm. The specimen is submitted for intraoperative consultation and entirely submitted in cassette E1FS. (Dictated by

Specimen F is received fresh along with patient's name, medical record number and labeled as buccal margin, stitch anterior, frozen section. The specimen consists of a strip of mucosa tissue which measures 4.0 x 0.5 x 0.3 cm. The specimen is submitted for intraoperative consultation and entirely submitted in cassette F1FS. (Dictated by

Specimen G is received fresh along with patient's name, medical record number and labeled as lower lip margin, stitch medial, frozen section. The specimen consists of a fragment of soft tissue which measures 6.7 x 0.7 x 0.3 cm. The stitch area is inked blue. The specimen is for intraoperative consultation and entirely submitted in cassette G1FS. (Dictated by

[page 5 of 6]
Specimen H is received fresh along with patient's name, medical record number and labeled as pterygoid muscle margin, frozen section. The specimen consists of a soft tissue fragment which measures 1.5 x 0.8 x 0.3 cm. The specimen is for intraoperative consultation and entirely submitted in cassette H1FS. (Dictated by

Specimen I is received fresh along with patient's name, medical record number and labeled as medial gingival margin, frozen section. The specimen consists of two segments of soft tissue which measure 0.7 x 0.4 x 0.1 cm and 0.6 x 0.1 x 0.1 cm respectively. The specimen is for intraoperative consultation and entirely submitted in cassette I1FS. (Dictated by

Specimen J is received fresh along with patient's name, medical record number and labeled as left level 2, fresh. The specimen consists of a portion of unoriented fibroadipose tissue fragment which measures 4.6 x 4.5 x 1.6 cm. A total of 9 potential lymph nodes are identified in the specimen. The largest one measures 1.5 cm in diameter. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

J1: One potential lymph node, bisected
J2: One potential lymph node, bisected
J3: One potential lymph node, bisected
J4: One potential lymph node, bisected
J5: One potential lymph node, bisected
J6: Two potential lymph nodes
J7: Two potential lymph nodes

Specimen K is received fresh along with patient's name, medical record number and labeled as left buccal fat. The specimen consists of unoriented fibroadipose tissue which measure 4.0 x 1.8 x 1.5 cm. Grossly no obvious lymph nodes are identified. The specimen is entirely submitted in cassettes K1 to K6 for potential lymph nodes. (Dictated by

Specimen L is received fresh along with patient's name, medical record number and labeled as hemimandibulectomy with neck contents level 1. The specimen consists of a hemimandibulectomy with surrounding soft tissue which measures 12 cm from anterior-to-posterior, 6.0 cm from lateral-to-medial and 7.2 cm from superior-to-inferior. A friable firm mass lesion is present in the center of the specimen which measures 4.6 cm from anterior-to-posterior, 4.0 cm from lateral-to-medial and 4.4 cm in depth. This mass lesion is 1.5 cm away from anterior bone margin, 0.2 cm away from medial soft tissue margin and 0.1 cm away from lateral soft tissue margin. This mass lesion is also abutting the submandibular gland. The cut surface of this mass lesion is white and firm. The attached submandibular gland measures 3.2 x 2.2 x 2.0 cm. Within it, there is a 1.8 x 1.5 x 1.0 cm firm, well-circumscribed nodular lesion which shows white appearance on cut surface. This nodular lesion within the submandibular gland is 2 cm away from the main mass lesion. Grossly the main mass lesion is also surrounding the mandibular body. No other lesions are present. The specimen is inked as follows: lateral soft tissue-blue, medial soft tissue-black. Along with the specimen, five teeth are attached (19, 20, 21, 22, 23). Grossly these teeth are unremarkable. Representative sections are submitted as follows. Cassettes L10 and L11 will be submitted after decalcification. (Dictated by

CASSETTE SUMMARY:

L1: Mass lesion closest to medial soft tissue margin
L2: Mass lesion closest to posterolateral soft tissue margin
L3: Mass lesion closest to anterior lateral soft tissue margin
L4, L5: Mass lesion in relation to submandibular gland
L6: Nodular lesion within the submandibular gland, closest deep margin
L7: Representative sections of uninvolved submandibular gland
L8, L9: Representative sections of mass lesion
L10: Mass lesion in relation to mandibular bone (bread-loafed)
L11: Anterior bone margin, shaved

Specimen M is received in formalin along with patient's name, medical record number and labeled as left sternocleidomastoid muscle. The specimen consists of a segment of unoriented muscle which measures 8.0 x 3.0 x 2.5 cm. No firm mass lesion is present. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

M1, M2: Representative sections of muscular tissue

[page 6 of 6]
Intraoperative Consult Diagnosis

D1FS: LEFT FLOOR MOUTH, SHAVE, (FROZEN SECTION): NEGATIVE FOR INVASIVE CARCINOMA.
E1FS: POSTERIOR PHARYNGEAL, SHAVE, (FROZEN SECTION): NEGATIVE FOR INVASIVE CARCINOMA.
F1FS: BUCCAL MARGIN, SHAVE, (FROZEN SECTION): ATYPICAL FOCUS CELLS SURROUNDED BY
CHRONIC
INFLAMMATION – FOCUS DISAPPEARS ON DEEPER FROZEN SECTIONS.
G1FS: LOWER LIP; SHAVE, (FROZEN SECTION): NEGATIVE FOR INVASIVE CARCINOMA.
H1FS: PTERYGOID, SHAVE, (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
11FS: MEDIAL GINGIVA , (FROZEN SECTION): BENIGN.
Frozen section results were communicated to the surgical team and were repeated back by on
at In at

Pathologist:

Microscopic Description

Microscopic examination of the decalcified specimen performed.

Source: NCI Genomic Data Commons file 2ed49bca-0119-477b-a0d3-b684d8f3fb4e (TCGA-QK-A6IH.EA914F6B-55C2-47C0-BB9F-196B2C17685F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).